Somatic mutation profile of tumor specimen C3L-02219-01 (aliquot CPT0104630009) from CPTAC case C3L-02219, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.6 years (28,347 days).
Specimen C3L-02219-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aa8ad26-5ee4-4e72-88cd-b3cad09d8a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02219-31 (Blood Derived Normal), aliquot CPT0105160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4059b4a-1ae6-4e31-ba54-8edca70e3eed

The open-access MAF lists 134 somatic variants for this specimen: 86 protein-altering or splice-affecting, 21 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 21, Intron 9, RNA 7, Nonsense Mutation 6, 3'UTR 5, 5'Flank 3, Splice Region 3, 5'UTR 2, Frame Shift Ins 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2572C>A p.L858M | Missense Mutation (SNP) | VAF 81/642 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913443, COSV51765969, COSV51766331; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 80/643 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2564C>G p.P855R | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101036936; called by muse, mutect2, varscan2
- AC099489.1 | c.4142C>A p.T1381K | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185420411, COSV60863010; called by muse, mutect2, varscan2
- CCDC170 | c.1764C>G p.D588E | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV53339854; called by muse, mutect2
- CEP170 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60511702; called by muse, mutect2
- COP1 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as COSV100442494; called by muse, mutect2
- DLL1 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816077; called by muse, mutect2
- DNAH11 | c.11135C>T p.A3712V | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs752746558; called by muse, mutect2, varscan2
- EDA | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV65777053; called by muse, mutect2, varscan2
- ELOVL4 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63954932; called by muse, mutect2
- EMX2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71294375; called by muse, mutect2
- FAHD1 | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 33/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66900562; called by muse, mutect2
- GNG7 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as rs1361825248; called by muse, mutect2
- ITSN2 | c.3331C>T p.H1111Y | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.813); catalogued as rs1367698367, COSV61946807; called by muse, mutect2
- KCNH1 | c.1388G>A p.S463N (on ENST00000271751 / NM_172362.3; = p.S436N on NM_002238.4) | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55082794; called by muse, mutect2
- MAP7D1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1386959956; called by muse, mutect2
- MSH5 | c.1407+8C>T | Splice Region (SNP) | VAF 24/268 reads (9%) | catalogued as rs1015965700; called by muse, mutect2
- MUC16 | c.8399G>A p.G2800E | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV67444199; called by muse, mutect2
- MUC3A | c.7472C>G p.T2491S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.14); catalogued as rs764477214; called by muse, mutect2, varscan2
- MYO1F | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 15/499 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs1357494338; called by muse, mutect2
- NCOR2 | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs757849016; called by muse, mutect2, varscan2
- NLRP5 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs771396943, COSV66762329; called by muse, mutect2, varscan2
- OR10K2 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs754197597; called by muse, mutect2
- OR51V1 | c.486dup p.I163Hfs*8 | Frame Shift Ins (INS) | VAF 26/302 reads (9%) | catalogued as rs573294390; called by mutect2, pindel
- PABPC4L | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs866386625, COSV101413742; called by muse, mutect2
- PARP9 | c.2102A>G p.H701R | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs558459007; called by muse, mutect2, varscan2
- PRR16 | c.325C>T p.H109Y (on ENST00000407149 / NM_001300783.2; = p.H86Y on NM_016644.2) | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.244); catalogued as rs1348471838; called by muse, mutect2, varscan2
- PYCARD | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as COSV56008593, COSV99910972; called by muse, mutect2
- RBM10 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 138/235 reads (59%) | catalogued as COSV61313425; called by muse, mutect2, varscan2
- SCGB1A1 | c.54C>T p.S18= | Splice Region (SNP) | VAF 14/62 reads (23%) | catalogued as rs370830538; called by muse, mutect2, varscan2
- SHANK1 | c.6443G>T p.R2148L | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53242336; called by muse, mutect2, varscan2
- SLC17A6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as rs773836933, COSV54136869; called by muse, mutect2, varscan2
- TENM3 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs866645611; called by muse, mutect2
- TERT | c.1575G>T p.G525= | Splice Region (SNP) | VAF 24/586 reads (4%) | catalogued as rs941123759; called by muse, mutect2
- TMEM234 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated, low confidence (0.54); catalogued as rs965152190; called by muse, mutect2, varscan2
- UTP25 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71966205; called by muse, mutect2
- ZNF568 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1052185970, COSV101426778; called by muse, mutect2
- ZNF679 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as rs765794959; called by muse, mutect2, varscan2
- ZZZ3 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs773254397; called by muse, mutect2, varscan2
- ALDOA | c.770A>G p.Q257R (on ENST00000642816 / NM_001243177.4; = p.Q203R on NM_184041.5) | Missense Mutation (SNP) | VAF 65/643 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4757G>T p.G1586V | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ANKS1B | c.1944C>G p.F648L | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4E1 | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATM | c.7194C>A p.Y2398* | Nonsense Mutation (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- ATP5F1C | c.861G>T p.L287F | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C19orf47 | c.382dup p.L128Pfs*23 | Frame Shift Ins (INS) | VAF 14/137 reads (10%) | called by mutect2, pindel, varscan2
- CCNK | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); called by muse, mutect2
- CPEB4 | c.706C>G p.H236D | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.632); called by muse, mutect2
- CRACD | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 29/265 reads (11%) | called by muse, mutect2, varscan2
- DCDC2C | c.681A>T p.Q227H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, varscan2
- DOC2A | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.101); called by muse, mutect2
- FADS3 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2
- FARP2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- FBXO31 | c.1205C>A p.P402Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FBXW7 | c.701_703del p.L234del (on ENST00000281708 / NM_001349798.2; = p.L154del on NM_018315.5) | In Frame Del (DEL) | VAF 19/132 reads (14%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.1251G>C p.M417I | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- GOLGA6L2 | c.513G>T p.L171F | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEY2 | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.77); called by muse, mutect2
- IGF2R | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 61/421 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MACROD2 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); called by muse, mutect2
- MRC1 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 19/548 reads (3%) | called by muse, mutect2
- MUC17 | c.7187G>T p.S2396I | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MUC22 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.07); called by muse, mutect2
- MYCBPAP | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- NLRP11 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRP1 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.309); called by muse, mutect2
- OR10H5 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH9 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA6 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.079); called by muse, mutect2
- PKN2 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PLAT | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- POTEE | c.2148G>T p.M716I | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); called by muse, mutect2
- PRDM12 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PXDNL | c.4048G>T p.A1350S | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHBG | c.1376A>T p.*459Lext*6 | Nonstop Mutation (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- SCX | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- SERPINA12 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SHD | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- SLC2A10 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNTG1 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- TMC2 | c.2230T>A p.F744I | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1996T>A p.L666M | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WAS | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZNF729 | c.2357A>T p.H786L | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- ZNF814 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, varscan2
- BCL11A | c.1137G>A p.A379= (on ENST00000335712 / NM_001365609.1; = p.A413= on NM_018014.4) | Silent (SNP) | VAF 16/326 reads (5%) | catalogued as rs1311687214, COSV59627243; called by muse, mutect2
- CLCN5 | c.1404T>C p.L468= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- FAM91A1 | c.2388A>G p.S796= | Silent (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- FERD3L | c.429C>T p.L143= | Silent (SNP) | VAF 73/246 reads (30%) | catalogued as COSV51764725; called by muse, mutect2, varscan2
- HAUS4 | c.858T>A p.I286= | Silent (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- HERC2 | c.8332C>T p.L2778= | Silent (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- KIF23 | c.2719C>A p.R907= (on ENST00000260363; = p.R803= on NM_004856.7) | Silent (SNP) | VAF 46/275 reads (17%) | catalogued as COSV52982244; called by muse, mutect2, varscan2
- KIF26B | c.3288G>T p.G1096= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as rs918882996; called by muse, mutect2, varscan2
- KRTAP9-4 | c.303C>T p.C101= | Silent (SNP) | VAF 62/525 reads (12%) | catalogued as COSV100484975; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1467C>T p.P489= | Silent (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- OR10A3 | c.597C>A p.A199= | Silent (SNP) | VAF 8/221 reads (4%) | catalogued as rs1390050303; called by muse, mutect2
- OR2C3 | c.750T>C p.S250= | Silent (SNP) | VAF 42/431 reads (10%) | called by muse, mutect2, varscan2
- OR6X1 | c.153C>T p.P51= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- PDIA6 | c.81C>T p.S27= | Silent (SNP) | VAF 23/207 reads (11%) | catalogued as rs1044048219; called by muse, mutect2, varscan2
- PURB | c.804C>T p.F268= | Silent (SNP) | VAF 26/482 reads (5%) | catalogued as rs1400954009; called by muse, mutect2
- ROCK2 | c.3363A>T p.S1121= | Silent (SNP) | VAF 22/221 reads (10%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1416C>T p.Y472= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV62417486; called by muse, mutect2
- SVIL | c.516G>T p.T172= | Silent (SNP) | VAF 29/235 reads (12%) | called by muse, mutect2, varscan2
- TFAP2B | c.444C>T p.D148= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs13216733; called by muse, mutect2
- VSTM2B | c.591C>T p.R197= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- ZNF536 | c.2097G>A p.G699= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs766026619; called by muse, mutect2, varscan2
- AC004837.1 | n.47C>T | RNA (SNP) | VAF 11/192 reads (6%) | catalogued as COSV69296740; called by muse, mutect2
- AC114741.1 | n.124G>A | RNA (SNP) | VAF 15/210 reads (7%) | catalogued as rs762418907; called by muse, mutect2
- ADCYAP1R1 | c.1046+2948C>T | Intron (SNP) | VAF 40/496 reads (8%) | catalogued as rs1025321164; called by muse, mutect2
- AL355390.1 | n.501G>A | RNA (SNP) | VAF 8/208 reads (4%) | called by muse, mutect2
- ALMS1P1 | chr2:73700986 G>T | 3'Flank (SNP) | VAF 27/289 reads (9%) | called by muse, mutect2
- BBX | c.162+722G>C | Intron (SNP) | VAF 5/124 reads (4%) | called by muse, mutect2
- C8A | c.*4C>T | 3'UTR (SNP) | VAF 19/209 reads (9%) | catalogued as rs1452187095; called by muse, mutect2
- DNAH14 | c.2939-76G>T | Intron (SNP) | VAF 23/177 reads (13%) | catalogued as rs1274452673; called by muse, mutect2, varscan2
- DOCK11 | c.-21G>A | 5'UTR (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- F13A1 | chr6:6320859 C>T | 5'Flank (SNP) | VAF 48/270 reads (18%) | called by muse, mutect2, varscan2
- FAM21FP | n.347C>A | RNA (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- HOXA6 | chr7:27151596 C>T | 5'Flank (SNP) | VAF 62/350 reads (18%) | catalogued as rs1013814250; called by muse, mutect2, varscan2
- HSPG2 | c.*2C>T | 3'UTR (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- LRRC37A3 | c.*6G>C | 3'UTR (SNP) | VAF 42/336 reads (13%) | called by muse, mutect2, varscan2
- MIR509-1 | n.82T>C | RNA (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- NRG2 | c.1189+377T>C | Intron (SNP) | VAF 28/447 reads (6%) | called by muse, mutect2
- PDE5A | c.152+1328A>G | Intron (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2
- RLN3 | c.191-385C>A | Intron (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- RLN3 | c.191-384C>A | Intron (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- SH3RF3 | chr2:109128927 C>T | 5'Flank (SNP) | VAF 9/47 reads (19%) | catalogued as rs938235314; called by muse, mutect2, varscan2
- SLC25A51P4 | n.736C>A | RNA (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- SPEF2 | c.4448-4208G>A | Intron (SNP) | VAF 16/519 reads (3%) | catalogued as rs908692469; called by muse, mutect2
- TLK1 | c.331-5740G>T | Intron (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- TPI1 | c.*227A>G | 3'UTR (SNP) | VAF 74/806 reads (9%) | called by muse, mutect2
- UQCRB | c.*3399C>T | 3'UTR (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- WDR35 | c.-6C>G | 5'UTR (SNP) | VAF 43/292 reads (15%) | called by muse, mutect2, varscan2
- ZNF833P | n.1089T>C | RNA (SNP) | VAF 41/177 reads (23%) | catalogued as rs1162911615; called by muse, mutect2, varscan2
